Surgical pathology report (de-identified scan), TCGA case TCGA-CJ-4902, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CJ-4902-01A (Primary Tumor).

Surgery Date: [REDACTED]

TCGA-CJ-4902

Pathology Report

DIAGNOSIS

(A) RIGHT KIDNEY:

RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, FUHRMAN NUCLEAR GRADE 3.

TUMOR MEASURES 8.0 CM IN GREATEST DIMENSION.

TUMOR FOCALLY INVADES THE PERINEPHRIC ADIPOSE TISSUE.

Resection margins free of tumor.

Portion of adrenal gland, no tumor present.

GROSS DESCRIPTION

(A) RIGHT KIDNEY - A right radical nephrectomy specimen (18.0 x 9.0 x 8.0 cm in toto). The right kidney measures 15.0 x 7.5 x 6.0 cm. The attached ureter measures 15.0 cm in length and 0.5 cm in diameter. The renal vein and artery measures 2.0 cm in length and 0.6 cm in average diameter.

A lobulated tumor (8.0 x 7.0 x 6.0 cm) is present at the lower pole of the kidney. Focally, tumor is seen invading through the capsule into the perinephric adipose tissue, 0.2 cm away from Gerota's fascia margin. The Gerota's fascia appears intact and not involved by the tumor. The tumor is tan-yellow with extensive hemorrhage and necrosis. Focally it has a gelatinous appearance. No sarcomatoid component is identified. The tumor does not grossly invade into the renal sinus and renal vein. The pelvicalyceal system is devoid of tumor. A small portion of adrenal gland (2.0 x 0.5 x 0.2 cm) is grossly unremarkable.

INK CODE: Black - Gerota's fascia.

SECTION CODE: A1, resection margin of the renal vein, artery and ureter; A2, tumor with Gerota's fascia; A3, tumor with capsule; A4, A5, tumor at the sinus; A6, tumor with adjacent kidney; A7, representative sections of tumor; A8, tumor in the perinephric fat; A9, A10, uninvolved kidney; A11, small portion of adrenal gland. [REDACTED]

CLINICAL HISTORY

Right renal mass.

SNOMED CODES

T-71000, M-83123

"

Source: NCI Genomic Data Commons file ca1fc78e-309b-46b3-851b-fc647beb8d61 (TCGA-CJ-4902.D9C1EDB2-4078-4F89-B2F0-6C10D8D8A9FF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).